Surgical pathology report (de-identified scan), TCGA case TCGA-50-6593, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-50-6593-01A (Primary Tumor).

[page 1 of 2]
PATIENT HISTORY:

PRE-OP DIAGNOSIS: Lung cancer.

POST-OP DIAGNOSIS: Not given.

PROCEDURE: Not given.

ADDENDA:

Addendum

Molecular Anatomic Pathology Testing:

Block 4C:

- A. *KRAS* codon 12/13 mutation NOT identified.
- B. *EGFR* Exon 19 mutation NOT identified.
- C. *EGFR* Exon 21 mutation NOT identified.
- D. *EGFR* amplification IDENTIFIED (see In Situ Procedure).
- E. *EML4/ALK* rearrangement NOT identified (see In Situ Procedure).

Note:

KRAS codon 12/13 mutations are found in approximately 10-30% lung adenocarcinomas and associated with history of smoking (1). *EGFR* exon 19 and 21 mutations are present in about 10% of non-Asians and up to 40% in the Asian population, common in non-smokers and associated with the tumor response to treatment with *EGFR* inhibitors (2). These mutations are mutually exclusive and their presence may have prognostic and/or therapeutic implications (3,4). Clinical studies show high *EGFR* gene copy number by FISH analysis (amplification) to be associated with favorable clinical benefit (clinical response, stable disease, time to progression, and survival) in patients with advanced non-small cell lung cancer treated with *EGFR* tyrosine kinase inhibitors.

Approximately 3% of lung adenocarcinomas within the Asian population have an interstitial deletion and inversion in chromosome 2p resulting in the *EML4/ALK* fusion gene (*ALK+*) which is sensitive to *ALK* inhibitors (5,6). The prevalence of this abnormality in the Western population is still unknown. Detection of this abnormality is critical for identifying patients eligible for therapies that target *ALK* enzymatic activity. *EML4/ALK* rearrangements are mutually exclusive with *KRAS* and *EGFR* mutations.

Addendum

Sections of the Part 2 "portion of fifth rib" show normal bone and bone marrow with trilineage representation and maturation.

FINAL DIAGNOSIS:

SUMMARY STATEMENT:

The right upper lobectomy demonstrates a poorly differentiated adenocarcinoma, 1.3 cm in diameter, with angiolymphatic invasion, unassociated with visceral pleural invasion, with involvement of both N1 and N2 lymph nodes and all margins free. Pathologic stage; T1 N2 Mx.

PART 1: LYMPH NODE, ANTERIOR HILAR LYMPH NODE, BIOPSY –
TWO (2) FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PART 2: BONE, "PORTION OF 5TH RIB", RESECTION –
SPECIMEN UNDERGOING DECALCIFICATION. AN ADDENDUM REPORT TO FOLLOW.

PART 3: LYMPH NODE, "LYMPH NODE NEAR ANTERIOR MAJOR FISSURE", BIOPSY –
SOLITARY LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF MALIGNANCY.

PART 4: LUNG, RIGHT UPPER LOBE, LOBECTOMY –
A. POORLY DIFFERENTIATED ADENOCARCINOMA, MIXED SOLID AND ACINAR TYPE, 1.3 CM IN DIAMETER WITH ANGIOLYMPHATIC INVASION. NO EVIDENCE OF VISCERAL PLEURAL INVASION. ALL MARGINS FREE. MILD HOST LYMPHOCYTIC RESPONSE. PATHOLOGIC STAGE T1 N2 MX.
B. FIVE OF SIX HILAR LYMPH NODES POSITIVE FOR METASTATIC ADENOCARCINOMA (5/6).
C. LUNG WITH MARKED EMPHYSEMATOUS CHANGE WITH RESPIRATORY BRONCHIOLITIS.

PART 5: BRONCHUS, "RIGHT UPPER LOBE BRONCHIAL MARGIN, RESECTION –

[page 2 of 2]
SEE COMMENT.

PART 6: LYMPH NODE, HILAR LYMPH NODE, BIOPSY –
ONE OF ONE LYMPH NODE WITH METASTATIC ADENOCARCINOMA (1/1).

PART 7: LYMPH NODE, BRONCHUS INTERMEDIUS, BIOPSY –
FOUR (4) FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF METASTATIC
CARCINOMA.

PART 8: LYMPH NODE, PARAESOPHAGEAL LYMPH NODE, BIOPSY –
FOUR (4) FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF METASTATIC
CARCINOMA.

PART 9: LYMPH NODE, SUBCARINAL LYMPH NODE, BIOPSY –
FIVE (5) FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF METASTATIC
CARCINOMA.

PART 10: LYMPH NODE, RIGHT PARATRACHEAL LYMPH NODE, BIOPSY –
TWO OF TWO LYMPH NODES WITH METASTATIC ADENOCARCINOMA (2/2).

PART 11: LYMPH NODE, RIGHT TRACHEOBRONCHIAL ANGLE, BIOPSY –
BENIGN FRAGMENTS OF FIBROADIPOSE TISSUE WITH CHRONIC INFLAMMATION AND EXTENSIVE CRUSH
ARTIFACT.

PART 12: LYMPH NODE, SUB-INNOMINATE LYMPH NODE, BIOPSY –
TWO (2) FRAGMENTS OF LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF METASTATIC
CARCINOMA.

PART 13: LYMPH NODE, PARATRACHEAL LYMPH NODE, BIOPSY –
SOLITARY LYMPH NODE WITH REACTIVE CHANGE. NO EVIDENCE OF METASTATIC CARCINOMA.

COMMENT:

Frozen sections performed on Part 5 "bronchial margin" shows that this margin is free of carcinoma, although marked crush change is present. Permanent sections of this bronchial margin do show adenocarcinoma within the adventitial cuff of the bronchus. While present in these permanent sections, the margin of resection is interpreted as negative but it should be noted that carcinoma extends within 1-2 mm of this final margin.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY LUNG TUMORS

TUMOR LOCATION:	Right Upper Lobe
PROCEDURE:	Lobectomy
TUMOR SIZE:	Maximum dimension: 1.3 cm Minor dimension: 1.0 cm
GROSS SATELLITES:	Number of gross satellite lesions: 0
TUMOR TYPE:	Invasive adenocarcinoma
HISTOLOGIC GRADE:	G3, Poorly differentiated
MICROSCOPIC SATELLITES:	Number of microscopic satellite lesions: 0
EXTRAPULMONARY PARENCHYMAL EXTENSION/INVASION OF TUMOR:	None identified
ANGIOLYMPHATIC INVASION:	Yes
TUMOR NECROSIS:	< or = to 50%

SURGICAL MARGIN INVOLVEMENT:	No
SURGICAL MARGIN SITE:	Distance of invasive tumor to closest margin: 12 mm, Bronchial margin
INFLAMMATORY(DESMOPLASTIC) REACTION:	Mild

N1 LYMPH NODES:	Number of N1 lymph nodes positive: 6 Number of N1 lymph nodes examined: 13
-----------------	---

EXTRACAPSULAR SPREAD OF N1 METASTASES:	No
N2 LYMPH NODES:	Number of N2 lymph nodes positive: 2 Number of N2 lymph nodes examined: 14

EXTRACAPSULAR SPREAD OF N2 METASTASES:	No
--	----

UNDERLYING DISEASE(S):	Emphysema
------------------------	-----------

T STAGE, PATHOLOGIC:	pT1
----------------------	-----

N STAGE, PATHOLOGIC:	pN2
----------------------	-----

M STAGE, PATHOLOGIC:	pMX
----------------------	-----

ANCILLARY STUDIES:	Histochemical stains, FISH studies, Molecular studies
--------------------	---

Comment:	PAS and PAS-D and mucicarmine stains are positive. Elastic tissue stains demonstrates vascular invasion.
----------	--

Source: NCI Genomic Data Commons file f94354c5-1b1f-4e79-b57a-b639c6632207 (TCGA-50-6593.61906551-B954-4723-BB64-33BD88CC57F6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).